Gene-level copy-number profile of tumor specimen ALCH-B2CV-TTP1-A from ALCHEMIST case ALCH-B2CV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.6 years (20,659 days).
Specimen ALCH-B2CV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c599ddaf-13d5-49c3-b784-0d47f21ad93d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2CV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/4e44564a-6f3f-4f66-bae2-c20708646f6d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 17,226; copy number 2: 36,806; copy number 3: 3,789; copy number 4: 355; copy number 5: 164; copy number 7: 4; copy number 8: 2; copy number 12: 2; copy number 20: 6.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:48,403,854–48,662,886, 18 genes: PLXNB1, CCDC51, TMA7, AC134772.1, ATRIP, TREX1, SHISA5, PFKFB4, MIR6823, UCN2, COL7A1, MIR711, UQCRC1, TMEM89, SLC26A6, MIR6824, CELSR3, MIR4793.
- chr4:51,978,079–51,978,372, 1 gene: AC104784.1.
- chr6:78,809,715–78,813,303, 1 gene: AL450327.1.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr10:94,865,852–94,873,129, 1 gene: CYP2C58P.
- chr10:95,141,925–95,184,217, 3 genes: AL157834.4, AL157834.3, PAWRP1.
- chr11:63,137,867–63,410,294, 6 genes (within-gene range 0–1): SLC22A10, SLC22A25, AP001880.2, CCND2P1, AP001880.1, SLC22A9.
- chr12:11,212,219–11,251,389, 1 gene: AC244131.2.
- chr15:64,815,632–64,825,668, 1 gene: PIF1.
- chr17:3,276,942–3,386,317, 2 genes (within-gene range 0–1): OR3A2, OR3A1.
- chr17:3,377,527–3,377,602, 1 gene (within-gene range 0–1): OR1AC1P.
- chr17:81,197,393–81,200,288, 1 gene (within-gene range 0–2): AC027601.2.
- chr22:18,615,581–18,625,289, 2 genes: Metazoa_SRP, SUSD2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 178 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,006,309–149,009,527, 1 gene, copy number 5 (within-gene range 4–5): AC239802.1.
- chr1:149,048,576–152,196,699, 161 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:18,418,775–18,419,273, 1 gene, copy number 5: BNIP3P6.
- chr14:18,601,045–18,602,129, 1 gene, copy number 5: OR11H12.
- chr14:18,634,955–18,637,421, 2 genes, copy number 8: CR383656.1, CR383656.12.
- chr22:18,178,038–18,530,573, 12 genes, copy number 7–20: FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.

Autosomal genes at a single copy (total copy number 1): 16,156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
